Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A94X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A94X-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS C53.9
QW 8/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix

- Moderately differentiated infiltrative squamous cell carcinoma.

Media	11/17/13	Yes	No
For Malignancy History			✓
Asynchronous Primary			✓
Use is (circle):	CHALLENGE	DISQUALIFIED	
Viewer Initials	MD	Date Reviewed	11/12/13

Source: NCI Genomic Data Commons file 2846ff30-d6b2-4d0d-afec-59b78e05b4a5 (TCGA-VS-A94X.434AA106-443D-4A8E-93AD-14DFFD8A2B76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).